Somatic mutation profile of tumor specimen TCGA-Z2-AA3V-06A (aliquot TCGA-Z2-AA3V-06A-11D-A397-08) from TCGA case TCGA-Z2-AA3V, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.8 years (21,112 days).
Specimen TCGA-Z2-AA3V-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8be3cf0d-3358-45b7-908f-66f3c44a0f19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Z2-AA3V-10A (Blood Derived Normal), aliquot TCGA-Z2-AA3V-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9d0c07f-afaf-478d-be5b-0a34e9a6efc8

The open-access MAF lists 520 somatic variants for this specimen: 335 protein-altering or splice-affecting, 178 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 302, Silent 178, Nonsense Mutation 22, RNA 4, Splice Region 4, Intron 3, Frame Shift Del 2, Splice Site 2, Nonstop Mutation 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1064794292, CM980322, COSV58684053, COSV58729667; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- F8 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852364, CM055225, CM890046, COSV64270460; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OPHN1 | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.415); catalogued as rs869312676, COSV100830838; ClinVar: likely pathogenic; called by mutect2, varscan2
- ABCA13 | c.14030G>T p.W4677L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV68950909; called by muse, mutect2, varscan2
- ABCA9 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100383583; called by muse, mutect2, varscan2
- ABCC9 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs746967404, COSV53962075, COSV53967382; called by muse, mutect2, varscan2
- AC098582.1 | c.2752C>A p.Q918K | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); catalogued as COSV99986097; called by muse, mutect2, varscan2
- ACAN | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV100719410; called by muse, mutect2
- ACSM2A | c.1021C>T p.L341F (on ENST00000219054; = p.L262F on NM_001308169.2) | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99525794; called by muse, mutect2, varscan2
- ACSM5 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV100088861; called by muse, mutect2, varscan2
- ACSS3 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759012460, COSV54086149; called by muse, mutect2, varscan2
- ADAM28 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as COSV56105281; called by muse, mutect2
- ADAMTS14 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV100941910; called by muse, mutect2, varscan2
- ADRA1A | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.871); catalogued as COSV52365059; called by muse, mutect2
- AFF2 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs782049601, COSV100648782, COSV60659728; called by muse, mutect2, varscan2
- AHCTF1 | c.3187C>T p.R1063* (on ENST00000366508; = p.R1037* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100404532; called by muse, mutect2, varscan2
- AIFM1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); catalogued as COSV99781489; called by muse, mutect2, varscan2
- ALPK3 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs994367118, COSV99362132; called by muse, mutect2, varscan2
- ALPK3 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99362134; called by muse, mutect2, varscan2
- ANGPT1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs868669098, COSV52433932; called by muse, mutect2, varscan2
- ANKRD12 | c.4400C>T p.S1467F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); catalogued as rs1257667371, COSV50836886; called by muse, mutect2, varscan2
- ANKRD13C | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99257827; called by muse, mutect2, varscan2
- AQP10 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV100270540; called by muse, mutect2, varscan2
- ARAF | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.222); catalogued as COSV51692146; called by muse, mutect2
- ARHGAP15 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs267598909, COSV99714135; called by muse, mutect2, varscan2
- ARHGAP20 | c.1442A>G p.N481S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs1330090215, COSV99505582; called by muse, mutect2, varscan2
- ARHGEF11 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV63815732; called by muse, mutect2, varscan2
- ARMCX1 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 37/189 reads (20%) | catalogued as COSV100863252; called by muse, mutect2, varscan2
- ASIC4 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs202143794; called by muse, mutect2, varscan2
- ATAD2 | c.1400G>C p.G467A | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99785424; called by muse, mutect2, varscan2
- ATP6V1D | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs754025532, COSV99371000; called by muse, mutect2, varscan2
- ATP6V1H | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 19/92 reads (21%) | catalogued as COSV100778878; called by muse, mutect2, varscan2
- BCAM | c.603G>A p.E201= | Splice Region (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99539036; called by muse, mutect2, varscan2
- BCLAF3 | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.509); catalogued as COSV100503293, COSV100503422; called by muse, mutect2, varscan2
- BMP5 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63704158; called by muse, mutect2, varscan2
- BMP7 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1230022035, COSV101216336; called by muse, mutect2, varscan2
- BMPER | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as COSV51821322; called by muse, mutect2, varscan2
- BST1 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs765296526, COSV53948801, COSV99400178; called by muse, mutect2, varscan2
- BTBD9 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1459905530, COSV100022941; called by muse, mutect2, varscan2
- C22orf42 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV66075230; called by muse, mutect2, varscan2
- C2CD3 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1223396697, COSV100076775; called by muse, mutect2, varscan2
- CABCOCO1 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100358120; called by muse, mutect2, varscan2
- CABP1 | c.676G>A p.E226K (on ENST00000316803 / NM_001033677.1; = p.E23K on NM_004276.5) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99974910; called by muse, mutect2, varscan2
- CACNG2 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100269143; called by muse, mutect2, varscan2
- CACNG2 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753303377, COSV100269146; called by muse, mutect2, varscan2
- CAD | c.5231C>T p.P1744L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs764067828, COSV99255930; called by muse, mutect2, varscan2
- CAPN6 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1278979927, COSV100137128; called by muse, mutect2, varscan2
- CBLN4 | c.292-1G>A p.X98_splice | Splice Site (SNP) | VAF 14/54 reads (26%) | catalogued as rs1313011277, COSV99290788; called by muse, mutect2, varscan2
- CCR1 | c.941A>G p.Q314R | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV99946827; called by muse, mutect2
- CD163L1 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV100550765; called by muse, mutect2, varscan2
- CD207 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV101338600; called by muse, mutect2
- CD33 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV51804747; called by muse, mutect2, varscan2
- CD96 | c.967G>A p.E323K (on ENST00000283285 / NM_198196.3; = p.E307K on NM_005816.5) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV99343682; called by muse, mutect2, varscan2
- CDK12 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV70999175; called by muse, mutect2, varscan2
- CES4A | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV100110301; called by muse, mutect2, varscan2
- CFAP65 | c.301C>T p.P101S (on ENST00000341552 / NM_194302.4; = p.P36S on NM_152389.4) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.21); catalogued as rs1264306512, COSV99838504; called by muse, mutect2, varscan2
- CHAF1B | c.1505T>C p.L502S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1202370787, COSV100023807; called by muse, mutect2, varscan2
- CHRNA4 | c.520A>C p.N174H | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV100937494; called by muse, mutect2, varscan2
- CHRNA5 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100214070; called by muse, mutect2, varscan2
- CHTOP | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.04); catalogued as rs148406634, COSV100904742; called by muse, mutect2, varscan2
- CHTOP | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.672); catalogued as rs1205842673, COSV100904743; called by muse, mutect2, varscan2
- CLCN2 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99659080; called by muse, mutect2, varscan2
- CLEC9A | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV63351306; called by muse, mutect2, varscan2
- CLK2 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs768170507, COSV100751949; called by muse, mutect2, varscan2
- CLMN | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.214); catalogued as rs537928595, COSV100112998; called by muse, mutect2, varscan2
- CLPB | c.1672T>A p.F558I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99578825; called by muse, mutect2, varscan2
- CNOT10 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.879); catalogued as COSV100095167; called by muse, mutect2, varscan2
- CNTN1 | c.1549A>T p.T517S | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as COSV100751982; called by muse, mutect2, varscan2
- CNTNAP4 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776621681, COSV100273632; called by muse, mutect2, varscan2
- CNTNAP5 | c.2447C>T p.S816F | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV70477966; called by muse, mutect2, varscan2
- COL4A4 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs771245112, COSV100307895; called by muse, mutect2, varscan2
- CRYBB1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs754432639, COSV99315994; called by muse, mutect2, varscan2
- CTAGE1 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as COSV101194708; called by muse, mutect2, varscan2
- CXCR2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59280121; called by muse, mutect2, varscan2
- CYP2E1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV99429278; called by muse, mutect2, varscan2
- DCT | c.966A>T p.L322F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.621); catalogued as COSV100986316; called by muse, mutect2, varscan2
- DGKH | c.2351C>T p.S784L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54929583; called by muse, mutect2, varscan2
- DLGAP4 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs1287550761, COSV100211672; called by muse, mutect2, varscan2
- DLK1 | c.1152A>T p.*384Yext*23 | Nonstop Mutation (SNP) | VAF 22/106 reads (21%) | catalogued as COSV100375489; called by muse, mutect2, varscan2
- DNAH5 | c.5648G>A p.R1883Q | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747514968, COSV54238992; called by muse, mutect2, varscan2
- DNAH5 | c.5086T>A p.L1696M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99455026; called by muse, mutect2
- DNAH8 | c.2363G>A p.G788E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1376949943, COSV100547362; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV59467992; called by muse, mutect2, varscan2
- DNAJC16 | c.1079T>A p.L360Q | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101012676; called by muse, mutect2, varscan2
- DNAJC5B | c.120-1G>A p.X40_splice | Splice Site (SNP) | VAF 15/144 reads (10%) | catalogued as COSV52535673; called by muse, mutect2, varscan2
- DNAJC6 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99674313; called by muse, mutect2, varscan2
- DSC2 | c.2593G>A p.V865M | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as COSV99199917; called by muse, mutect2, varscan2
- DSCAM | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as rs780067485, COSV68027076; called by muse, mutect2, varscan2
- EBF1 | c.1270C>T p.L424F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.726); catalogued as rs1436085936, COSV58179917; called by muse, mutect2, varscan2
- ECE1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV51670410; called by muse, mutect2, varscan2
- EFTUD2 | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 25/120 reads (21%) | catalogued as COSV99493931, COSV99494053; called by muse, mutect2, varscan2
- EPPIN-WFDC6 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.068); catalogued as COSV100323405; called by muse, mutect2, varscan2
- ERAP2 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1229133455, COSV101163956; called by muse, mutect2, varscan2
- FAM120A | c.1882T>A p.F628I | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV99466766; called by muse, mutect2, varscan2
- FAM9A | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.329); catalogued as COSV101121376; called by muse, mutect2
- FAT4 | c.4129A>G p.K1377E | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.986); catalogued as COSV101272914; called by muse, mutect2, varscan2
- FAT4 | c.6751G>A p.D2251N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs780126185, COSV100630444; called by muse, mutect2, varscan2
- FATE1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV64848992; called by muse, mutect2
- FBXL13 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1308416668, COSV100502228; called by muse, mutect2, varscan2
- FLOT1 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.191); catalogued as COSV100013494; called by muse, mutect2, varscan2
- FYCO1 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99946350; called by muse, mutect2, varscan2
- GALNT13 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67214636; called by muse, mutect2, varscan2
- GALNT13 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV101222247, COSV67243847; called by muse, mutect2
- GALNT14 | c.1334A>T p.K445M | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100205731; called by muse, mutect2, varscan2
- GALNTL6 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs866179630, COSV72489194; called by muse, mutect2, varscan2
- GBA3 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs762931123, COSV72438380; called by muse, mutect2
- GK2 | c.898C>T p.L300F | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100726059; called by muse, mutect2, varscan2
- GLT8D2 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100674285, COSV62562267; called by muse, mutect2, varscan2
- GLYR1 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 30/110 reads (27%) | catalogued as COSV100424522; called by muse, mutect2, varscan2
- GMDS | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV66442167; called by muse, mutect2, varscan2
- GPC4 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV100895617; called by muse, mutect2, varscan2
- GPR84 | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99910161; called by muse, mutect2, varscan2
- GRB10 | c.1531G>A p.G511R (on ENST00000398812; = p.G465R on NM_001001549.3) | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100241248; called by muse, mutect2, varscan2
- GRHL3 | c.163G>A p.D55N (on ENST00000350501 / NM_198174.3; = p.D60N on NM_021180.3) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV99359762; called by muse, mutect2
- GRID2 | c.10T>A p.F4I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV99947729; called by muse, mutect2, varscan2
- GRIK2 | c.2323C>T p.R775* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100022709, COSV59753542; called by muse, mutect2, varscan2
- GRIK3 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.066); catalogued as rs777066849, COSV100902256, COSV100902404, COSV100902522; called by muse, mutect2, varscan2
- GRIN2B | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); catalogued as rs1295510907, COSV74204691; called by muse, mutect2, varscan2
- GRM5 | c.2519C>T p.S840F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100554856, COSV100555296, COSV59613824; called by muse, mutect2, varscan2
- GTF2H4 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs753854558, COSV99462349; called by mutect2, varscan2
- HARS2 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51227037; called by muse, mutect2, varscan2
- HCN4 | c.2456C>T p.A819V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.074); catalogued as rs980872364, COSV99984338; called by muse, mutect2, varscan2
- HEATR5A | c.5128A>T p.S1710C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV101120653; called by muse, mutect2, varscan2
- HEPH | c.3301C>T p.P1101S (on ENST00000343002; = p.P834S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.186); catalogued as COSV100295883; called by muse, mutect2, varscan2
- HS3ST5 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100451479; called by muse, mutect2, varscan2
- HSD17B3 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100931311, COSV64556298; called by muse, mutect2, varscan2
- IGF2BP3 | c.1524A>T p.K508N | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.523); catalogued as COSV99325943; called by muse, mutect2, varscan2
- IL15RA | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs1352422115, COSV101181920; called by muse, mutect2, varscan2
- IL15RA | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.085); catalogued as COSV101181921; called by muse, mutect2, varscan2
- IL22RA1 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.04); catalogued as COSV99583321; called by muse, mutect2
- IL6ST | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100411089, COSV61143317; called by muse, mutect2, varscan2
- INTS1 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as COSV101248399; called by muse, mutect2, varscan2
- INTS10 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.661); catalogued as COSV101208754; called by muse, mutect2, varscan2
- INTS13 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99677674; called by muse, mutect2, varscan2
- IPP | c.1436G>C p.G479A | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.3); catalogued as COSV100739739; called by muse, mutect2, varscan2
- ITGA4 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs1354333812, COSV67899184; called by muse, mutect2, varscan2
- JADE1 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs774236013, COSV56903821; called by muse, mutect2, varscan2
- JPT2 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV50189092; called by muse, mutect2, varscan2
- KAAG1 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV99219856; called by muse, mutect2, varscan2
- KANK1 | c.134T>C p.F45S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100620148; called by muse, mutect2, varscan2
- KCNA2 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100316145; called by muse, mutect2, varscan2
- KCNJ8 | c.191T>A p.L64* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99557750; called by muse, mutect2, varscan2
- KDM3B | c.2960C>T p.S987L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV100070321; called by muse, mutect2, varscan2
- KDM4B | c.2974C>T p.L992F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99347584; called by muse, mutect2, varscan2
- KDR | c.3686G>A p.R1229Q | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.943); catalogued as rs776015468, COSV55758511; called by muse, mutect2, varscan2
- KDR | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV55761338; called by muse, mutect2, varscan2
- KIAA0319L | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100357778; called by muse, mutect2, varscan2
- KIAA1522 | c.2326C>T p.P776S (on ENST00000373480 / NM_001198972.2; = p.P835S on NM_020888.3) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV99615229; called by muse, mutect2, varscan2
- KIAA1522 | c.2327C>T p.P776L (on ENST00000373480 / NM_001198972.2; = p.P835L on NM_020888.3) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99615231; called by muse, mutect2, varscan2
- KLF5 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66614473; called by muse, mutect2, varscan2
- KLHL14 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.995); catalogued as COSV100839325; called by muse, mutect2, varscan2
- KLHL6 | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429797234, COSV100385102; called by muse, mutect2, varscan2
- KLK5 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100307268; called by muse, mutect2
- KRT15 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV99563331; called by muse, mutect2, varscan2
- KRT72 | c.619T>A p.L207M | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV99537532; called by muse, mutect2, varscan2
- KYAT3 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.511); catalogued as COSV99557123; called by muse, mutect2, varscan2
- LCE1E | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.999); catalogued as rs748788769, COSV64219528; called by muse, mutect2, varscan2
- LIN7A | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54021762; called by muse, mutect2, varscan2
- LMBRD1 | c.1156C>T p.P386S (on ENST00000649011; = p.P364S on NM_018368.4) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100992728; called by muse, mutect2
- LPP | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs201370939, COSV57088218; called by muse, mutect2, varscan2
- LRP1 | c.576C>T p.N192= | Splice Region (SNP) | VAF 8/37 reads (22%) | catalogued as rs748684528, COSV54522963; called by muse, mutect2, varscan2
- LRP1B | c.9128A>G p.N3043S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); catalogued as COSV101261828; called by muse, mutect2, varscan2
- LRP1B | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs145092192, COSV67197624, COSV67249343; called by muse, mutect2, varscan2
- LRP2 | c.10762C>T p.L3588F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99790557; called by muse, mutect2, varscan2
- LRRC4C | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.839); catalogued as COSV53441849, COSV99540019; called by muse, mutect2, varscan2
- LTBP2 | c.4954C>T p.R1652W | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142182623; called by muse, mutect2, varscan2
- MACROD2 | c.961G>A p.E321K (on ENST00000642719; = p.E293K on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as COSV99445111; called by muse, mutect2, varscan2
- MAGEA10 | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as COSV54884837; called by muse, mutect2, varscan2
- MAGEC1 | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.048); catalogued as rs771890346, COSV53573197; called by muse, mutect2, varscan2
- MAP1A | c.3988T>G p.L1330V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100289353; called by muse, mutect2, varscan2
- MAP9 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100251151; called by muse, mutect2, varscan2
- MARCHF4 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99814875; called by muse, mutect2, varscan2
- MAST4 | c.3992C>A p.S1331Y (on ENST00000403625 / NM_001164664.2; = p.S1142Y on NM_015183.3) | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99846209; called by muse, mutect2, varscan2
- MATN3 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1195531515, COSV101337485; called by muse, mutect2, varscan2
- MCF2 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV58488655; called by muse, mutect2, varscan2
- MCUR1 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV101001919; called by muse, mutect2, varscan2
- MED23 | c.3559C>T p.P1187S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as COSV100645437; called by muse, mutect2, varscan2
- MEP1B | c.1458T>A p.D486E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as COSV99329191; called by muse, mutect2, varscan2
- MFSD5 | c.776T>C p.F259S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100289181; called by muse, mutect2, varscan2
- MGA | c.6665C>T p.S2222F (on ENST00000219905 / NM_001164273.1; = p.S2013F on NM_001080541.2) | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.188); catalogued as COSV99581877; called by muse, mutect2, varscan2
- MICALL2 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs151320299; called by muse, mutect2, varscan2
- MRGPRX1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs771155598, COSV100246174; called by muse, mutect2, varscan2
- MRGPRX2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs564709381, COSV100316872; called by muse, mutect2, varscan2
- MS4A6E | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100279180, COSV55726861; called by muse, mutect2, varscan2
- MTUS2 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV70916928; called by muse, mutect2, varscan2
- MUC2 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); catalogued as rs377546134; called by muse, mutect2, varscan2
- MUC4 | c.13912C>T p.P4638S (on ENST00000463781 / NM_018406.7; = p.P402S on NM_004532.6) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100206765; called by muse, mutect2, varscan2
- MUC5B | c.6215C>T p.T2072M | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs771277633, COSV101500859; called by muse, mutect2, varscan2
- MYH13 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs371327620; called by muse, mutect2, varscan2
- MYOM1 | c.3535G>A p.E1179K | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.824); catalogued as COSV99868688; called by muse, mutect2, varscan2
- NEK11 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100797726, COSV100797938; called by muse, mutect2, varscan2
- NEK8 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV52042471, COSV52049188; called by muse, mutect2, varscan2
- NEU3 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs758788013, COSV99579834; called by muse, mutect2, varscan2
- NEXN | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as COSV53943163, COSV99630705; called by muse, mutect2, varscan2
- NFASC | c.799G>A p.E267K (on ENST00000339876 / NM_001378329.1; = p.E278K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV100366053; called by muse, mutect2, varscan2
- NIBAN1 | c.2540G>A p.G847D | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1407309928, COSV100836339; called by muse, mutect2, varscan2
- NID2 | c.1134T>A p.D378E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs999020684, COSV53500287; called by muse, mutect2, varscan2
- NLGN4X | c.1940C>T p.P647L | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99324301; called by muse, mutect2, varscan2
- NLRC3 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751013625, COSV100073520; called by muse, mutect2, varscan2
- NLRP8 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.127); catalogued as COSV52587818; called by muse, mutect2, varscan2
- NOL10 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV100630333; called by muse, mutect2, varscan2
- NONO | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV52137317, COSV52141002; called by muse, mutect2, varscan2
- NOVA1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as COSV57472701, COSV57490260; called by muse, mutect2, varscan2
- NPAS3 | c.194G>A p.G65E (on ENST00000356141 / NM_001164749.2; = p.G35E on NM_022123.3) | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.953); catalogued as COSV100390282; called by muse, mutect2, varscan2
- NPY5R | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.209); catalogued as COSV58451831; called by muse, mutect2, varscan2
- NSD1 | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); catalogued as rs773655381, COSV100729887; called by muse, mutect2, varscan2
- NUP153 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs780097780, COSV100020926; called by muse, mutect2, varscan2
- NYNRIN | c.4273C>T p.P1425S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV101230721; called by muse, mutect2, varscan2
- OLFML2A | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99992929; called by muse, mutect2, varscan2
- OR10G2 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.067); catalogued as COSV101606974, COSV73390448; called by muse, mutect2, varscan2
- OR13C3 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101053346, COSV101053365; called by muse, mutect2, varscan2
- OR2H1 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 38/159 reads (24%) | catalogued as COSV101009945; called by muse, mutect2, varscan2
- OR2T6 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1301503755, COSV100861657, COSV63217207; called by muse, mutect2, varscan2
- OR4K15 | c.659G>A p.S220N (on ENST00000305051; = p.S196N on NM_001005486.1) | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV100521182; called by muse, mutect2, varscan2
- OR51G1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs200001303; called by muse, mutect2, varscan2
- OR52A5 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV56617372; called by muse, mutect2
- OR52I2 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100443030; called by muse, mutect2, varscan2
- OR52M1 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1315065954, COSV100798624; called by muse, mutect2, varscan2
- OR52M1 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV100798625; called by muse, mutect2, varscan2
- OR52N1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100398576; called by muse, mutect2, varscan2
- OR5AP2 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100266475, COSV57258684; called by muse, mutect2, varscan2
- OR5H6 | c.563A>G p.N188S (on ENST00000642105; = p.N172S on NM_001005479.2) | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs765483499, COSV101051824; called by muse, mutect2
- OR8H1 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs373192147; called by muse, mutect2
- PACRG | c.378T>A p.F126L | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as COSV100435286; called by muse, mutect2, varscan2
- PAH | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as CM930544, COSV61015784; called by muse, mutect2, varscan2
- PARM1 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV56661756; called by muse, mutect2, varscan2
- PAX5 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs865878221, COSV100814480; called by muse, mutect2, varscan2
- PCDHA3 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.043); catalogued as COSV100974176; called by muse, mutect2, varscan2
- PCDHA6 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100971909; called by muse, mutect2, varscan2
- PCLO | c.7820G>A p.G2607E | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100438826; called by muse, mutect2, varscan2
- PCSK1 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552958813, COSV100227304; called by muse, varscan2
- PCSK9 | c.629A>C p.E210A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100135616; called by muse, mutect2, varscan2
- PDE1A | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV100116660; called by muse, mutect2, varscan2
- PDYN | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99453415; called by muse, mutect2, varscan2
- PHF1 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100992699; called by muse, mutect2, varscan2
- PIAS2 | c.582C>T p.S194= | Splice Region (SNP) | VAF 10/29 reads (34%) | catalogued as COSV61342057; called by muse, mutect2, varscan2
- PIEZO2 | c.7732A>T p.K2578* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99555647; called by muse, mutect2, varscan2
- PIGT | c.907A>T p.T303S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.192); catalogued as COSV99649269; called by muse, mutect2, varscan2
- PKDREJ | c.4511G>A p.G1504E | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99478585; called by muse, mutect2, varscan2
- PLCH1 | c.703G>A p.E235K (on ENST00000340059 / NM_001130960.2; = p.E247K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58196739; called by muse, mutect2
- PLD1 | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100644100; called by muse, mutect2, varscan2
- POU6F1 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100374926; called by muse, mutect2, varscan2
- PPP2R2B | c.878G>A p.G293E (on ENST00000394409; = p.G359E on NM_181674.2) | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100356470, COSV60761202; called by muse, mutect2, varscan2
- PRAMEF20 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs202075096; called by muse, mutect2, varscan2
- PRDM15 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); catalogued as rs1488025518, COSV54155382; called by muse, mutect2, varscan2
- PRDM9 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV57004159, COSV99691416; called by mutect2, varscan2
- PRICKLE1 | c.2258G>A p.G753E | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100454328; called by muse, mutect2, varscan2
- PRKCA | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV99436411; called by muse, mutect2
- PRRT3 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.846); catalogued as rs1336766165, COSV99926776; called by muse, mutect2, varscan2
- PSG6 | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV99414430; called by muse, mutect2, varscan2
- PXN | c.911C>G p.P304R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57222397, COSV99936404; called by muse, mutect2, varscan2
- R3HDM1 | c.2284G>A p.G762R | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51528132, COSV99926927; called by muse, mutect2, varscan2
- RANBP3L | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150799200, COSV56955472; called by muse, mutect2
- RAPGEF5 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV100688011, COSV59792296; called by muse, mutect2, varscan2
- RBM46 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as rs1342343562, COSV99908475; called by muse, mutect2
- RBMS3 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56131991, COSV99824652; called by muse, mutect2
- RGS6 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV100667130; called by muse, mutect2, varscan2
- RHCG | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV51518793; called by muse, mutect2, varscan2
- RNF40 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as rs1345582972, COSV61214777; called by muse, mutect2, varscan2
- RPL32 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV99832861; called by muse, mutect2, varscan2
- RPS4X | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100289185; called by muse, mutect2, varscan2
- RPTN | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 135/583 reads (23%) | catalogued as COSV100285868; called by muse, mutect2, varscan2
- RUSC2 | c.3392T>C p.I1131T | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100770928; called by muse, mutect2, varscan2
- RYR3 | c.12073G>A p.E4025K (on ENST00000389232; = p.E4026K on NM_001036.6) | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs573502706, COSV66778841; called by muse, mutect2, varscan2
- SACS | c.3133G>A p.E1045K | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV101207783; called by muse, mutect2, varscan2
- SCAPER | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763733575, COSV57742632; called by muse, mutect2, varscan2
- SCML2 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV99318510, COSV99318733; called by muse, mutect2, varscan2
- SCN11A | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56566746, COSV56569749; called by muse, mutect2, varscan2
- SCN9A | c.3448G>A p.E1150K (on ENST00000303354; = p.E1139K on NM_002977.3) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as rs367794835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SELENOP | c.1120A>G p.K374E | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs1262940622, COSV100736930; called by muse, mutect2, varscan2
- SELPLG | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.566); catalogued as COSV99947756; called by muse, mutect2, varscan2
- SERPIND1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs762809184, COSV53140517; called by muse, mutect2, varscan2
- SETBP1 | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); catalogued as rs146222882; called by muse, mutect2, varscan2
- SEZ6L | c.2378G>A p.W793* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | catalogued as rs1232513307, COSV99963106; called by muse, mutect2, varscan2
- SHROOM2 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101099132; called by mutect2, varscan2
- SLC1A2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99555149; called by muse, mutect2, varscan2
- SLC1A2 | c.1422G>A p.L474= | Splice Region (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99555150; called by muse, mutect2, varscan2
- SLC22A23 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100978444; called by muse, mutect2, varscan2
- SLC26A2 | c.182A>T p.K61I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.536); catalogued as COSV99640437; called by muse, mutect2, varscan2
- SLC9A6 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs782469016, COSV100857958; called by muse, mutect2, varscan2
- SLCO1B1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs138965366; called by muse, mutect2, varscan2
- SLIT3 | c.2471C>T p.S824F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100270408; called by muse, mutect2, varscan2
- SLITRK3 | c.2617C>T p.P873S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV53854463; called by muse, mutect2, varscan2
- SPATS2L | c.1586G>A p.R529K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV100660899; called by muse, mutect2
- SPEG | c.8759C>T p.P2920L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1213008375, COSV100405840; called by muse, mutect2, varscan2
- SPHK2 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.941); catalogued as COSV99709680; called by muse, mutect2, varscan2
- SPTB | c.1793A>T p.K598I | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV101072451; called by muse, mutect2, varscan2
- SRBD1 | c.2798G>T p.G933V | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55406835, COSV99765657; called by muse, mutect2, varscan2
- STK31 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.069); catalogued as COSV100669653; called by muse, mutect2, varscan2
- TBC1D9B | c.3596C>A p.S1199Y (on ENST00000356834 / NM_198868.3; = p.S1182Y on NM_015043.4) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV99481842; called by muse, mutect2, varscan2
- TDRD5 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV54241692; called by muse, mutect2, varscan2
- TFDP3 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100033125, COSV100033582; called by muse, mutect2, varscan2
- THAP12 | c.780T>A p.F260L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99473308; called by muse, mutect2, varscan2
- THSD7B | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as rs1472577978, COSV99758960; called by muse, mutect2, varscan2
- TMC8 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV100531704; called by muse, mutect2
- TMEM117 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99863890; called by muse, mutect2, varscan2
- TMEM132B | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54745471; called by muse, mutect2, varscan2
- TMEM132B | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.913); catalogued as COSV100169269, COSV54758862; called by muse, mutect2, varscan2
- TMEM132D | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101398637; called by muse, mutect2, varscan2
- TMEM132D | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101399792; called by muse, mutect2, varscan2
- TMEM177 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55608138, COSV99733760; called by muse, mutect2, varscan2
- TMEM63C | c.1955T>C p.I652T | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100029851; called by muse, mutect2, varscan2
- TMPRSS11F | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as rs542655796, COSV62464715; called by muse, mutect2, varscan2
- TRA2A | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99767910; called by muse, mutect2, varscan2
- TRAK2 | c.2621T>A p.L874* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100217207; called by muse, mutect2, varscan2
- TRANK1 | c.2826G>A p.M942I | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs867298982, COSV100085051; called by muse, mutect2, varscan2
- TRIM60 | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV100594172, COSV61972253; called by muse, mutect2, varscan2
- TST | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | catalogued as COSV99968263; called by muse, mutect2
- TTC3 | c.580T>G p.L194V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100696118; called by muse, mutect2, varscan2
- TTLL6 | c.1829A>T p.K610I (on ENST00000393382 / NM_001130918.3; = p.K303I on NM_173623.3) | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100938243; called by muse, mutect2, varscan2
- TTN | c.46093G>A p.D15365N (on ENST00000591111; = p.D7941N on NM_003319.4) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | PolyPhen benign (0.403); catalogued as COSV100633515; called by muse, mutect2, varscan2
- UBP1 | c.866A>T p.K289I | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99372946; called by muse, mutect2, varscan2
- UBP1 | c.865A>C p.K289Q | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV99372949; called by muse, mutect2, varscan2
- UNC13C | c.1732C>T p.L578F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52891126, COSV99523749; called by muse, mutect2
- UNK | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV99505653; called by muse, mutect2, varscan2
- URAD | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); catalogued as COSV100229649; called by muse, mutect2, varscan2
- VCAN | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99427559; called by muse, mutect2, varscan2
- VILL | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99378785, COSV99379340; called by muse, mutect2
- ZACN | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs898873151, COSV100135861; called by muse, mutect2
- ZBTB38 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759226254, COSV58543389; called by muse, mutect2, varscan2
- ZBTB40 | c.2815C>T p.H939Y | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100989127; called by muse, mutect2, varscan2
- ZC3H3 | c.949T>A p.S317T | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as COSV99368731; called by muse, mutect2, varscan2
- ZFHX4 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99268590; called by muse, mutect2, varscan2
- ZFPM2 | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554583195, COSV101023660; ClinVar: uncertain significance; called by mutect2, varscan2
- ZNF462 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV99473535; called by muse, mutect2, varscan2
- ZNF479 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 20/140 reads (14%) | catalogued as COSV58639288; called by muse, mutect2, varscan2
- ZNF98 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV63334101; called by muse, mutect2, varscan2
- ZRANB3 | c.1852C>T p.P618S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99924616, COSV99925011; called by muse, mutect2, varscan2
- IGKV3-7 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- SLC27A6 | c.725del p.L242* | Frame Shift Del (DEL) | VAF 32/173 reads (18%) | called by mutect2, pindel, varscan2
- UBE2NL | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- VPS35L | c.1790_1802del p.Q597Pfs*7 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel
- ZNF768 | c.691_708del p.M231_L236del | In Frame Del (DEL) | VAF 33/107 reads (31%) | called by mutect2, pindel, varscan2
- ACSM5 | c.1470C>T p.A490= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV100089661; called by muse, mutect2, varscan2
- ACTA1 | c.294G>A p.V98= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs1323268291, COSV100796806; called by muse, mutect2, varscan2
- ADAMTS14 | c.3159C>T p.P1053= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs954925508, COSV100941911; called by muse, mutect2, varscan2
- ADCY4 | c.1329C>T p.T443= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs1193564966, COSV100156907; called by muse, mutect2, varscan2
- AKR1D1 | c.744G>A p.G248= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV54340878; called by muse, mutect2, varscan2
- ALDH1B1 | c.879C>T p.I293= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs141592792; called by muse, mutect2, varscan2
- AMZ2 | c.696C>T p.F232= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs781970033, COSV100703250; called by muse, mutect2, varscan2
- ANKRD11 | c.2847G>A p.R949= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV99970815; called by muse, mutect2, varscan2
- ANO3 | c.2907G>A p.R969= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as rs866532902, COSV56805197; called by muse, mutect2, varscan2
- APBA1 | c.2190G>A p.K730= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as COSV99595980, COSV99597291; called by muse, mutect2, varscan2
- APOB | c.3519G>A p.K1173= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99268523; called by muse, mutect2, varscan2
- ARHGEF11 | c.81C>T p.S27= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV63812605; called by muse, mutect2, varscan2
- ARX | c.138C>T p.A46= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100984092, COSV66874849; called by muse, mutect2
- ASIC4 | c.282C>T p.T94= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs769639891, COSV100761952; called by muse, mutect2, varscan2
- ASPHD1 | c.267C>T p.S89= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV100435942; called by muse, mutect2, varscan2
- BSN | c.2727C>T p.L909= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99610030; called by muse, mutect2
- BSN | c.6003C>T p.I2001= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs760360093, COSV56520032; called by muse, mutect2, varscan2
- BTBD9 | c.540C>T p.S180= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV100022216; called by muse, mutect2, varscan2
- C2CD3 | c.231C>T p.P77= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100076765; called by muse, mutect2, varscan2
- C3 | c.1429C>T p.L477= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV99837369; called by muse, mutect2, varscan2
- C3 | c.1428C>T p.L476= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs1301962534, COSV55573449; called by muse, mutect2, varscan2
- CATSPERB | c.1137A>G p.K379= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV99831905; called by muse, mutect2, varscan2
- CCDC185 | c.1368C>T p.F456= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100838826, COSV64820159; called by muse, mutect2, varscan2
- CCDC33 | c.123C>T p.L41= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs1370427349, COSV100351920; called by muse, mutect2, varscan2
- CCDC60 | c.1425C>T p.I475= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as COSV100555635, COSV59548479; called by muse, mutect2, varscan2
- CCNT2 | c.1428T>C p.S476= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99751293; called by muse, mutect2, varscan2
- CD81 | c.222C>T p.F74= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs775840442, COSV55133785; called by muse, mutect2, varscan2
- CDH20 | c.2334G>A p.T778= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs552739283, COSV53018130; called by muse, mutect2, varscan2
- CFAP47 | c.4497G>A p.L1499= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100545761; called by muse, mutect2, varscan2
- CHRNA4 | c.519G>A p.Q173= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV100937495; called by muse, mutect2, varscan2
- CHRNB2 | c.858C>T p.I286= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as rs865998992, COSV63808978; called by muse, mutect2, varscan2
- CKMT1A | c.774C>T p.F258= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV101376812; called by muse, mutect2, varscan2
- CLCN2 | c.2214G>A p.S738= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs144202469; called by muse, mutect2, varscan2
- CLIP1 | c.423C>T p.P141= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as rs1209770307, COSV100212484; called by muse, mutect2, varscan2
- CLMN | c.2013G>A p.E671= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV100112999; called by muse, mutect2, varscan2
- CNOT10 | c.66G>A p.G22= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100095170; called by muse, mutect2, varscan2
- COLEC10 | c.603G>A p.K201= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs748590459, COSV100250951, COSV60522639; called by muse, mutect2, varscan2
- CPD | c.1911C>T p.F637= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV99853344; called by muse, mutect2, varscan2
- CRAMP1 | c.963C>T p.V321= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99246477; called by muse, mutect2
- CRTAP | c.1183T>C p.L395= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100310228; called by muse, mutect2, varscan2
- CSMD1 | c.1329C>T p.T443= (on ENST00000520002; = p.T442= on NM_033225.6) | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs761037658, COSV101226433; called by muse, mutect2, varscan2
- CYP17A1 | c.681A>G p.K227= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100882152; called by muse, mutect2
- CYP2F1 | c.348C>T p.S116= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV100463062; called by muse, mutect2, varscan2
- CYP4F3 | c.519C>T p.I173= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as COSV99658777; called by muse, mutect2, varscan2
- CYP4Z1 | c.192G>A p.K64= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs766985096; called by muse, mutect2, varscan2
- DCLK3 | c.342G>A p.L114= | Silent (SNP) | VAF 45/187 reads (24%) | catalogued as rs756521183, COSV101374163; called by muse, mutect2, varscan2
- DCP1A | c.165C>T p.F55= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs554406616, COSV53688313; called by muse, mutect2, varscan2
- DISP2 | c.3042C>T p.L1014= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs767233498; called by muse, mutect2
- DISP3 | c.2811C>T p.F937= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as rs776634246, COSV53825449; called by muse, mutect2, varscan2
- DNAH10 | c.7392G>A p.R2464= (on ENST00000409039; = p.R2403= on NM_207437.3) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV101292901; called by muse, mutect2
- DRC7 | c.648C>T p.C216= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs1326262329, COSV100395941; called by muse, mutect2, varscan2
- DSC3 | c.840G>A p.L280= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100844764; called by muse, mutect2, varscan2
- DTNA | c.2182C>T p.L728= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99315825; called by muse, mutect2, varscan2
- DYSF | c.2676G>A p.G892= | Silent (SNP) | VAF 34/170 reads (20%) | catalogued as COSV99250888; called by muse, mutect2, varscan2
- EID2B | c.312C>T p.S104= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100411066; called by muse, mutect2, varscan2
- EMILIN1 | c.1548C>T p.S516= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs374940182, COSV53155722, COSV53156318; called by muse, mutect2, varscan2
- FAM120C | c.933T>C p.F311= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100070510; called by muse, mutect2, varscan2
- FGFR4 | c.324C>T p.I108= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs781632034, COSV52800788; called by muse, mutect2, varscan2
- FLOT1 | c.1098G>A p.E366= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100013496; called by muse, mutect2, varscan2
- FMN2 | c.3825G>A p.G1275= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV60441644; called by muse, mutect2, varscan2
- FOXS1 | c.225C>T p.C75= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV99640318; called by muse, mutect2
- GPX6 | c.84G>A p.R28= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV62656893; called by muse, mutect2, varscan2
- GRM5 | c.2520T>C p.S840= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs758811858, COSV100554851; called by muse, mutect2, varscan2
- GSDMA | c.1122C>T p.F374= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as rs867925022, COSV52856602; called by muse, mutect2, varscan2
- HECW2 | c.1146C>A p.P382= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV99649276; called by muse, mutect2, varscan2
- HLA-G | c.933C>T p.I311= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs778011464, COSV64405282; called by muse, mutect2
- HS6ST2 | c.612C>T p.F204= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100897509; called by muse, mutect2, varscan2
- IBTK | c.1990C>T p.L664= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV100091604; called by muse, mutect2, varscan2
- IL22RA1 | c.1401C>T p.P467= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV99583318; called by muse, mutect2
- IL22RA2 | c.408G>A p.R136= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV99760858; called by muse, mutect2, varscan2
- INPP5D | c.2730C>T p.I910= (on ENST00000445964 / NM_001017915.3; = p.I909= on NM_005541.5) | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV64038512; called by muse, mutect2, varscan2
- INTS1 | c.921C>T p.S307= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as rs1321332162, COSV101248401; called by muse, varscan2
- INTS10 | c.210C>T p.F70= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV101208753; called by muse, mutect2, varscan2
- IQGAP1 | c.3816C>T p.V1272= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as COSV51592079; called by muse, mutect2, varscan2
- KALRN | c.2685C>T p.L895= | Silent (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- KCNA6 | c.1044G>A p.R348= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99769029; called by muse, mutect2, varscan2
- KLHDC7A | c.2145C>T p.A715= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV101272866; called by muse, mutect2, varscan2
- KPTN | c.552A>G p.E184= | Silent (SNP) | VAF 41/142 reads (29%) | catalogued as rs1362077603, COSV100583565; called by muse, mutect2, varscan2
- LAMA2 | c.5992T>C p.L1998= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV101370906; called by muse, mutect2, varscan2
- LRP1B | c.11913C>T p.P3971= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as COSV101261827; called by muse, mutect2, varscan2
- LRRIQ4 | c.516G>A p.L172= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100540418; called by muse, mutect2, varscan2
- LTBP2 | c.4953C>T p.F1651= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100001081; called by muse, mutect2, varscan2
- M1AP | c.1467T>A p.A489= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV99284250; called by muse, mutect2
- MAGI1 | c.969G>A p.T323= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as rs267599924, COSV58333620; called by muse, mutect2, varscan2
- MAP9 | c.327C>T p.A109= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV100251150; called by muse, mutect2, varscan2
- MCF2 | c.1452C>T p.S484= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs1353468842, COSV100644800, COSV100645229; called by muse, mutect2, varscan2
- MCHR2 | c.606G>A p.T202= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs267600746; called by muse, mutect2, varscan2
- MKLN1 | c.762C>T p.I254= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100760048; called by muse, mutect2, varscan2
- MMP16 | c.297C>T p.P99= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as rs769760558, COSV99690717; called by muse, mutect2, varscan2
- MSH5 | c.1659C>T p.V553= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100994863; called by muse, mutect2, varscan2
- MTUS2 | c.279C>T p.A93= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV101462393; called by muse, mutect2, varscan2
- MUL1 | c.582C>T p.T194= | Silent (SNP) | VAF 50/137 reads (36%) | catalogued as COSV99939470; called by muse, mutect2, varscan2
- MXRA5 | c.8052C>T p.T2684= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV99479662; called by muse, mutect2, varscan2
- MYH13 | c.1923G>A p.G641= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1342575418, COSV52820349; called by muse, mutect2, varscan2
- MYH2 | c.1548C>T p.F516= | Silent (SNP) | VAF 42/135 reads (31%) | catalogued as rs747082271, COSV55445586; called by muse, mutect2, varscan2
- NDUFB4 | c.300C>T p.F100= | Silent (SNP) | VAF 39/257 reads (15%) | catalogued as COSV99481965; called by muse, mutect2, varscan2
- NRXN1 | c.2076G>A p.R692= | Silent (SNP) | VAF 40/217 reads (18%) | catalogued as rs267599408, COSV100453385; called by muse, mutect2, varscan2
- NSG2 | c.201C>T p.I67= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs770102568, COSV100292960; called by muse, mutect2, varscan2
- OAS2 | c.1692C>T p.P564= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs1230772697, COSV60802736; called by muse, mutect2, varscan2
- OBP2A | c.318G>A p.G106= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100535770; called by muse, mutect2, varscan2
- OR11L1 | c.948T>C p.S316= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100869504; called by muse, mutect2, varscan2
- OR13C3 | c.621C>T p.F207= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as rs779347800, COSV66165647; called by muse, mutect2, varscan2
- OR14I1 | c.798C>T p.S266= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs1040308351, COSV100700551; called by muse, mutect2, varscan2
- OR2F1 | c.78C>T p.S26= | Silent (SNP) | VAF 32/150 reads (21%) | catalogued as rs771614966, COSV67331426; called by muse, mutect2, varscan2
- OR2K2 | c.606C>T p.I202= (on ENST00000374428; = p.I173= on NM_205859.2) | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs144434655; called by muse, mutect2, varscan2
- OR2T11 | c.294C>T p.I98= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100424991; called by muse, mutect2, varscan2
- OR3A2 | c.597C>T p.S199= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs202057099, COSV68695244; called by muse, mutect2, varscan2
- OSBPL2 | c.379C>T p.L127= (on ENST00000313733 / NM_144498.4; = p.L115= on NM_014835.4) | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100569366; called by muse, mutect2, varscan2
- PAX3 | c.237C>T p.S79= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99286880; called by muse, mutect2
- PCDHA11 | c.312C>T p.I104= | Silent (SNP) | VAF 46/248 reads (19%) | catalogued as rs1444507177, COSV100255430; called by muse, mutect2, varscan2
- PCLO | c.4182G>A p.K1394= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs1243207279, COSV100438830; called by muse, mutect2, varscan2
- PEG3 | c.1506G>A p.G502= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV99690080; called by muse, mutect2, varscan2
- PIK3R4 | c.150C>T p.V50= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as rs759836189, COSV63239246; called by muse, mutect2, varscan2
- PKD2 | c.858C>T p.S286= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as CD993523, COSV99417970; called by muse, mutect2, varscan2
- PLCH1 | c.1428C>T p.L476= (on ENST00000340059 / NM_001130960.2; = p.L488= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/130 reads (8%) | catalogued as rs745886014, COSV100398445; called by muse, mutect2
- PLEKHA4 | c.1683G>A p.R561= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV54363343, COSV99613400; called by muse, mutect2, varscan2
- PLEKHS1 | c.105T>C p.S35= (on ENST00000369310 / NM_182601.1; = p.S41= on NM_024889.5) | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100733003; called by muse, mutect2, varscan2
- PLG | c.966C>T p.N322= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV51987095, COSV99805203; called by muse, mutect2, varscan2
- PPP2R2B | c.879G>A p.G293= (on ENST00000394409; = p.G359= on NM_181674.2) | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100356467; called by muse, mutect2, varscan2
- PTPRD | c.3456G>A p.G1152= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs1301214098, COSV61934563; called by muse, mutect2, varscan2
- PXN | c.912C>T p.P304= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs543388127, COSV99936401; called by muse, mutect2, varscan2
- RABGAP1L | c.1600C>T p.L534= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV99274798; called by muse, mutect2, varscan2
- RELN | c.9510C>T p.S3170= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV59039841; called by muse, mutect2, varscan2
- RNF40 | c.327C>T p.L109= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV100222391; called by muse, mutect2, varscan2
- ROR2 | c.1404C>T p.I468= | Silent (SNP) | VAF 178/401 reads (44%) | catalogued as rs1252834866, COSV100996161; called by muse, mutect2, varscan2
- RORC | c.1159C>T p.L387= | Silent (SNP) | VAF 62/255 reads (24%) | catalogued as COSV100562164; called by muse, mutect2, varscan2
- RPRD1A | c.595C>T p.L199= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV59823698; called by muse, mutect2, varscan2
- SCN2A | c.2169G>A p.Q723= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV99333849; called by muse, mutect2, varscan2
- SCN5A | c.4530C>T p.I1510= (on ENST00000333535 / NM_198056.3; = p.I1509= on NM_000335.5) | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs372002687; called by muse, mutect2
- SCN9A | c.1593C>T p.T531= | Silent (SNP) | VAF 47/254 reads (19%) | catalogued as COSV100314449; called by muse, mutect2, varscan2
- SCUBE1 | c.2577G>A p.K859= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100683828; called by muse, mutect2, varscan2
- SELPLG | c.720G>A p.E240= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as rs771847261, COSV57311646, COSV99947758; called by muse, mutect2, varscan2
- SFSWAP | c.2055G>A p.R685= | Silent (SNP) | VAF 42/199 reads (21%) | catalogued as COSV99906467; called by muse, mutect2, varscan2
- SLC10A2 | c.342C>T p.I114= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs200413765, COSV99808341; called by muse, mutect2, varscan2
- SLC12A2 | c.864C>T p.I288= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs139820355; called by muse, mutect2, varscan2
- SLC1A1 | c.696G>A p.K232= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs755209040, COSV52058026, COSV99261643; called by muse, mutect2, varscan2
- SLC1A2 | c.240C>T p.F80= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99555152; called by muse, mutect2, varscan2
- SLC2A6 | c.1029C>T p.F343= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs782665778, COSV99390476; called by muse, mutect2
- SLC35F4 | c.15C>T p.L5= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100334310; called by muse, mutect2, varscan2
- SLC39A12 | c.1170C>T p.F390= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV101070194; called by muse, mutect2, varscan2
- SLC6A5 | c.693C>T p.I231= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs779239043, COSV54225243; called by muse, mutect2, varscan2
- SLC6A8 | c.1296C>T p.L432= | Silent (SNP) | VAF 39/149 reads (26%) | catalogued as COSV99466396; called by muse, mutect2, varscan2
- SPAG5 | c.528C>T p.P176= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV100410908; called by muse, mutect2, varscan2
- SPATS2L | c.1587G>A p.R529= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs1482676735, COSV100660900, COSV62351340; called by muse, mutect2
- SPTA1 | c.2652C>T p.L884= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV100935690; called by muse, mutect2, varscan2
- SPTBN1 | c.6999C>T p.V2333= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs199584027, COSV63334721; called by muse, mutect2, varscan2
- SULF1 | c.987G>A p.G329= | Silent (SNP) | VAF 39/251 reads (16%) | catalogued as COSV52682379; called by muse, mutect2, varscan2
- SUV39H1 | c.1164C>T p.L388= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV61920287; called by muse, mutect2, varscan2
- SYT1 | c.900G>A p.L300= | Silent (SNP) | VAF 43/171 reads (25%) | catalogued as COSV54069248; called by muse, mutect2, varscan2
- TAF1 | c.3597G>A p.E1199= (on ENST00000373790 / NM_138923.4; = p.E1220= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV99337217; called by muse, mutect2, varscan2
- TBC1D9B | c.3597C>T p.S1199= (on ENST00000356834 / NM_198868.3; = p.S1182= on NM_015043.4) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99481740; called by muse, mutect2, varscan2
- TBL3 | c.181C>T p.L61= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV100225134; called by muse, mutect2, varscan2
- TEP1 | c.57C>T p.N19= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs964077466, COSV99403405; called by muse, mutect2, varscan2
- TERT | c.1725C>T p.F575= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV57246983; called by muse, mutect2, varscan2
- THSD7B | c.303T>C p.S101= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99758957; called by muse, mutect2, varscan2
- TMC1 | c.1090C>T p.L364= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs764926506, COSV99920671; called by muse, mutect2, varscan2
- TMC8 | c.735G>A p.K245= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV59208987; called by muse, mutect2
- TMEM177 | c.567C>T p.Y189= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs114486427, COSV55609935; called by muse, mutect2, varscan2
- TMEM198 | c.471C>T p.G157= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99525913; called by muse, mutect2, varscan2
- TMLHE | c.354C>T p.F118= | Silent (SNP) | VAF 70/303 reads (23%) | catalogued as COSV100545145; called by muse, mutect2, varscan2
- TNFRSF8 | c.954T>C p.A318= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1296877324, COSV99822002; called by muse, mutect2, varscan2
- TPO | c.87C>T p.L29= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100222349; called by muse, mutect2, varscan2
- TRBV27 | c.90C>T p.L30= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1183535894; called by muse, mutect2, varscan2
- TRPV6 | c.1524C>T p.F508= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs200231244, COSV63893254, COSV63893634; called by muse, mutect2
- TSHZ2 | c.741G>A p.K247= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1482353798, COSV100296870; called by muse, mutect2, varscan2
- TTC37 | c.1800T>C p.C600= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100706941; called by muse, mutect2, varscan2
- UBE4B | c.333C>T p.V111= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV99477820; called by muse, varscan2
- UNC79 | c.1707C>T p.F569= (on ENST00000393151 / NM_001346218.2; = p.F392= on NM_020818.5) | Silent (SNP) | VAF 35/191 reads (18%) | catalogued as rs367698889; called by muse, mutect2, varscan2
- URB2 | c.2646C>T p.F882= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs559764814, COSV99272044; called by muse, mutect2, varscan2
- VCAM1 | c.795G>A p.G265= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs745861809, COSV99658986; called by muse, mutect2, varscan2
- VNN3 | c.573C>T p.F191= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV51591057; called by muse, mutect2, varscan2
- WSCD1 | c.1218C>T p.I406= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100496871; called by muse, mutect2, varscan2
- XIRP2 | c.303G>C p.L101= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV54725261, COSV99748278; called by muse, mutect2, varscan2
- YIPF4 | c.276C>T p.I92= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV53213073; called by muse, mutect2, varscan2
- ZBTB16 | c.879G>A p.R293= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1176908997, COSV100252246, COSV60101279; called by muse, mutect2, varscan2
- ZNF174 | c.919C>T p.L307= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs766592309, COSV99237780; called by muse, mutect2, varscan2
- ZNF331 | c.606C>T p.L202= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs757223836, COSV99468063; called by muse, mutect2, varscan2
- ZXDC | c.219C>T p.D73= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100306658; called by muse, mutect2, varscan2
- AC133065.1 | n.439-1260G>A | Intron (SNP) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- C8orf31 | n.669C>T | RNA (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- LEPR | c.2673+3160G>A | Intron (SNP) | VAF 7/24 reads (29%) | catalogued as rs1252582947, COSV100756552; called by muse, mutect2, varscan2
- OR2W5 | n.367C>T | RNA (SNP) | VAF 10/50 reads (20%) | catalogued as rs771959550; called by muse, mutect2, varscan2
- RCC1 | c.73+647C>T | Intron (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100868208; called by muse, mutect2, varscan2
- SLC22A17 | n.789C>T | RNA (SNP) | VAF 7/25 reads (28%) | catalogued as rs1290497621, COSV99249102; called by muse, mutect2, varscan2
- SSPOP | n.6689T>A | RNA (SNP) | VAF 5/32 reads (16%) | catalogued as rs763129081, COSV100023066; called by muse, mutect2
